Somatic mutation profile of tumor specimen 0DRIWA from CCDI case PBCGNX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Sarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 15.3 years (5,582 days).
Specimen 0DRIWA: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fdcca70e-8e14-443c-b4f1-1bc7719fba7a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRIWI (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/75d97533-3575-447a-ae8e-4079e2ae1db4

The open-access MAF lists 61 somatic variants for this specimen: 42 protein-altering or splice-affecting, 11 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 11, Nonsense Mutation 6, Intron 4, 3'UTR 3, 5'UTR 1, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1031T>G p.V344G | Missense Mutation (SNP) | VAF 264/342 reads (77%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1057519941, COSV55876054, COSV55895486, COSV55974473; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TRAPPC9 | c.2491C>T p.R831* | Nonsense Mutation (SNP) | VAF 334/819 reads (41%) | catalogued as rs373701249; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TRPM1 | c.1900C>T p.R634* | Nonsense Mutation (SNP) | VAF 230/547 reads (42%) | catalogued as rs763546583, COSV99856201; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARHGEF19 | c.688C>T p.R230W | Missense Mutation (SNP) | VAF 166/404 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); catalogued as COSV54619011, COSV99579943; called by muse, mutect2, varscan2
- BCS1L | c.490G>A p.G164R | Missense Mutation (SNP) | VAF 353/846 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV55308380; called by muse, mutect2, varscan2
- CCDC162P | n.2888G>A | Splice Region (SNP) | VAF 27/678 reads (4%) | catalogued as rs1030088340; called by muse, mutect2
- DENND2A | c.967G>A p.G323R | Missense Mutation (SNP) | VAF 335/891 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.14); catalogued as rs750694634; called by muse, mutect2, varscan2
- FCHO1 | c.1828G>A p.G610R | Missense Mutation (SNP) | VAF 157/387 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as rs747787856, COSV53180570; called by muse, varscan2
- FOXN2 | c.803T>C p.L268S | Missense Mutation (SNP) | VAF 711/1701 reads (42%) | SIFT tolerated (0.42); PolyPhen benign (0.164); catalogued as rs372003312; called by muse, mutect2, varscan2
- FRS3 | c.1142G>A p.R381H | Missense Mutation (SNP) | VAF 87/181 reads (48%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.489); catalogued as rs373318996, COSV52484258, COSV52485041; called by muse, mutect2, varscan2
- H1-7 | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 326/783 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as rs1398378737; called by muse, mutect2, varscan2
- KIRREL3 | c.2105C>T p.S702L | Missense Mutation (SNP) | VAF 247/614 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs754543011; called by muse, mutect2, varscan2
- KRT15 | c.640C>T p.R214* | Nonsense Mutation (SNP) | VAF 465/1080 reads (43%) | catalogued as rs767019289, COSV54179412; called by muse, mutect2, varscan2
- LAMB4 | c.785G>A p.R262Q | Missense Mutation (SNP) | VAF 515/1113 reads (46%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.659); catalogued as rs377732422, COSV52728386; called by muse, mutect2, varscan2
- MACROD1 | c.772C>G p.R258G | Missense Mutation (SNP) | VAF 184/412 reads (45%) | SIFT tolerated (0.4); PolyPhen benign (0.011); catalogued as rs758192787, COSV55357097; called by mutect2, varscan2
- MYO1E | c.839C>T p.A280V | Missense Mutation (SNP) | VAF 553/1348 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as rs375751619; called by muse, mutect2, varscan2
- MYO3B | c.3904G>A p.D1302N | Missense Mutation (SNP) | VAF 238/637 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as rs758960879; called by muse, mutect2, varscan2
- MYO7B | c.4117G>A p.V1373I | Missense Mutation (SNP) | VAF 269/631 reads (43%) | SIFT tolerated (0.97); PolyPhen benign (0.069); catalogued as rs761760742, COSV67344401; called by muse, mutect2, varscan2
- OAS2 | c.751G>A p.V251I | Missense Mutation (SNP) | VAF 392/904 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.024); catalogued as rs768169767, COSV60804667; called by muse, mutect2, varscan2
- PLEKHA4 | c.740G>A p.R247H | Missense Mutation (SNP) | VAF 184/251 reads (73%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs1381531122, COSV54360812; called by muse, mutect2, varscan2
- PLEKHG4B | c.1580C>T p.T527M (on ENST00000283426; = p.T883M on NM_052909.5) | Missense Mutation (SNP) | VAF 229/554 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.212); catalogued as rs138857981; called by muse, mutect2, varscan2
- PRAMEF12 | c.391C>T p.R131* | Nonsense Mutation (SNP) | VAF 294/772 reads (38%) | catalogued as rs201386508; called by muse, mutect2, varscan2
- RASGRF2 | c.2419G>A p.D807N | Missense Mutation (SNP) | VAF 470/1220 reads (39%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.015); catalogued as rs751344080, COSV99430403; called by muse, mutect2, varscan2
- SELENON | c.989G>A p.R330Q | Missense Mutation (SNP) | VAF 366/869 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.062); catalogued as rs758037272, COSV100823489; called by muse, mutect2, varscan2
- SIDT1 | c.2029C>T p.R677* | Nonsense Mutation (SNP) | VAF 377/492 reads (77%) | catalogued as rs150137878; called by muse, mutect2, varscan2
- SIRT6 | c.266C>T p.A89V | Missense Mutation (SNP) | VAF 192/394 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs750344205; called by muse, mutect2, varscan2
- SLITRK3 | c.2450A>C p.E817A | Missense Mutation (SNP) | VAF 542/713 reads (76%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV53851918; called by muse, mutect2, varscan2
- TIMP2 | c.284C>T p.S95L | Missense Mutation (SNP) | VAF 291/1189 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as rs1273715615, COSV53163366; called by muse, mutect2, varscan2
- ADAMTSL3 | c.1549A>G p.N517D | Missense Mutation (SNP) | VAF 512/1232 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ADIPOR2 | c.469G>A p.V157I | Missense Mutation (SNP) | VAF 316/708 reads (45%) | SIFT tolerated (0.35); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- APCS | c.262G>A p.G88R | Missense Mutation (SNP) | VAF 37/1483 reads (2%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.695); called by muse, mutect2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 97/2370 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- FBN3 | c.5692T>C p.C1898R | Missense Mutation (SNP) | VAF 37/833 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- GNA14 | c.1057A>G p.N353D | Missense Mutation (SNP) | VAF 44/992 reads (4%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.993); called by muse, mutect2
- KAZN | c.2216A>G p.H739R | Missense Mutation (SNP) | VAF 292/801 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- KCNG1 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 349/751 reads (46%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.531); called by muse, mutect2, varscan2
- KITLG | c.368T>G p.L123R | Missense Mutation (SNP) | VAF 233/1366 reads (17%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- PHKA2 | c.2361-2A>G p.X787_splice | Splice Site (SNP) | VAF 249/622 reads (40%) | called by muse, mutect2, varscan2
- PKDCC | c.383C>T p.P128L | Missense Mutation (SNP) | VAF 118/269 reads (44%) | SIFT tolerated (0.6); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- SLC30A6 | c.267C>G p.S89R | Missense Mutation (SNP) | VAF 167/569 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- SNED1 | c.2725C>A p.P909T | Missense Mutation (SNP) | VAF 62/1080 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.942); called by muse, mutect2
- SUFU | c.895C>T p.R299* | Nonsense Mutation (SNP) | VAF 349/454 reads (77%) | called by muse, mutect2, varscan2
- BHLHE41 | c.1059C>T p.F353= | Silent (SNP) | VAF 189/442 reads (43%) | catalogued as rs768789017; called by muse, mutect2, varscan2
- CDC25B | c.180C>T p.H60= | Silent (SNP) | VAF 329/788 reads (42%) | catalogued as rs1222243171; called by muse, mutect2, varscan2
- CSMD1 | c.2646C>T p.N882= (on ENST00000520002; = p.N881= on NM_033225.6) | Silent (SNP) | VAF 290/784 reads (37%) | catalogued as rs370427726; called by muse, mutect2, varscan2
- ERCC6L | c.2130C>T p.F710= | Silent (SNP) | VAF 359/777 reads (46%) | catalogued as rs755940524; called by muse, mutect2, varscan2
- GPLD1 | c.1386C>T p.D462= | Silent (SNP) | VAF 215/486 reads (44%) | catalogued as rs1062506, COSV100015424; called by muse, mutect2, varscan2
- MRTFA | c.2196C>T p.P732= | Silent (SNP) | VAF 124/279 reads (44%) | catalogued as rs748627198, COSV62933751; called by muse, mutect2, varscan2
- NRDC | c.3219G>A p.K1073= | Silent (SNP) | VAF 460/1182 reads (39%) | catalogued as COSV100544029; called by muse, mutect2, varscan2
- OR4M1 | c.396T>C p.Y132= | Silent (SNP) | VAF 535/1401 reads (38%) | catalogued as rs1256540667; called by muse, mutect2, varscan2
- PLXNA2 | c.2829G>A p.T943= | Silent (SNP) | VAF 367/919 reads (40%) | catalogued as rs373842883; called by muse, mutect2, varscan2
- TNS3 | c.1674A>G p.R558= | Silent (SNP) | VAF 245/598 reads (41%) | called by muse, mutect2, varscan2
- ZNF335 | c.1578C>T p.D526= | Silent (SNP) | VAF 396/1031 reads (38%) | catalogued as rs370067542; called by muse, mutect2, varscan2
- ADCY10 | c.293-19G>A | Intron (SNP) | VAF 250/601 reads (42%) | catalogued as rs202022950; called by muse, mutect2, varscan2
- AMPD2 | c.2158-25G>A | Intron (SNP) | VAF 158/418 reads (38%) | called by muse, mutect2, varscan2
- ATP1A2 | c.-84C>T | 5'UTR (SNP) | VAF 115/270 reads (43%) | catalogued as rs981682686, COSV100767600; called by muse, mutect2, varscan2
- NSMCE3 | c.*91G>T | 3'UTR (SNP) | VAF 28/412 reads (7%) | catalogued as rs1555434761; called by muse, mutect2
- NSMCE3 | c.*90A>T | 3'UTR (SNP) | VAF 28/422 reads (7%) | called by muse, mutect2
- ST18 | c.2363+35A>G | Intron (SNP) | VAF 313/726 reads (43%) | called by muse, mutect2, varscan2
- TMEM114 | c.*69G>A | 3'UTR (SNP) | VAF 53/131 reads (40%) | catalogued as rs1169107798; called by muse, mutect2, varscan2
- TMEM52B | c.138-19G>A | Intron (SNP) | VAF 160/427 reads (37%) | catalogued as rs7487375; called by muse, mutect2, varscan2
